Somatic mutation profile of tumor specimen MP2PRT-PAUJYI-TMP1-A (aliquot MP2PRT-PAUJYI-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUJYI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (835 days).
Specimen MP2PRT-PAUJYI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29a30f78-8171-4910-a72d-6d1a9dd202bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJYI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJYI-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94d66bc5-2a14-48cb-805b-21e4814b081f

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 83/256 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CCDC62 | c.245G>T p.R82I | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53435438; called by muse, mutect2, varscan2
- FAT2 | c.12446C>T p.P4149L | Missense Mutation (SNP) | VAF 100/394 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV55823208; called by muse, mutect2
- HTR1A | c.1160G>A p.W387* | Nonsense Mutation (SNP) | VAF 104/361 reads (29%) | catalogued as COSV100109106; called by muse, mutect2, varscan2
- MRGPRX2 | c.575T>A p.I192N | Missense Mutation (SNP) | VAF 80/281 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs760596682, COSV100316881; called by muse, mutect2, varscan2
- PCDHB15 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 208/696 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); catalogued as COSV50858094; called by muse, mutect2, varscan2
- PPP1R2B | c.62C>T p.T21M | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs1364347671; called by muse, mutect2, varscan2
- IGHV4-34 | chr14:106373654 CACTGTGCCTCTC>TCGTAAG | Missense Mutation (DEL) | VAF 79/185 reads (43%) | called by pindel, varscan2*
- SCT | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 96/285 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, varscan2
- TRGJP1 | chr7:38276308 del ACCAGTGGTATCAC | Missense Mutation (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- ABCA3 | c.2409G>A p.T803= | Silent (SNP) | VAF 87/252 reads (35%) | catalogued as rs777406810, COSV100068737; called by muse, mutect2, varscan2
- PCDHGA12 | c.1962C>A p.L654= | Silent (SNP) | VAF 248/771 reads (32%) | catalogued as COSV52762682; called by muse, mutect2, varscan2
